Surgical pathology report (de-identified scan), TCGA case TCGA-HT-8015, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-8015-01B (Primary Tumor).

Pathology Report for [REDACTED]

Addendum Discussion:

The neoplastic cells are diffusely immunoreactive for GFAP. In addition, the GFAP and neurofilament immunohistochemistry stain demonstrates in addition to relatively solid areas, the tumor does diffusely infiltrate the gray and white matter. The neoplastic cells are immunoreactive for P53. In most areas, the tumor is infiltrative with NeuN positivity among the tumor cells is not specific. In the most solid area of the tumor, there is a suggestion of weak NeuN positivity within the tumor cells but this positivity is much weaker than the surrounding neurons. The reticulin stain does not demonstrate investment of individual cells. Overall, the findings are suggestive of a diffusely infiltrative glioma. In the solid areas of tumor, scattered MIB-1 reactive cells are present with an estimated labeling index of 3-5%, consistent with a low grade process.

Addendum Diagnosis:

Diffuse well-differentiated Astrocytoma (WHO grade II).

Microscopic Description:

Sections demonstrate fragments of gray and white brain matter. A focus of markedly increased cellularity is identified. Cells within this area appear to be glial in origin. They are mainly small with round to ovoid nuclei. Few of the cells are larger and demonstrate prominent nucleoli. Mitotic figures are not seen. Few neurons surrounding the focus demonstrate enlarged nuclei with prominent nucleoli. 4B also demonstrates a nodular focus of large fibrillary astrocytes with somewhat glassy fibrillary cytoplasm. Also, scattered more atypical cells are seen. A rare binucleate cell is noted. Possible eosinophilic granular bodies are seen.

Source: NCI Genomic Data Commons file 50388670-e5f2-4acb-80a7-ae6ea9bdcc1f (TCGA-HT-8015.555DEE9A-4BA2-4E0A-A76E-06972079094A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).